Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3V0, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3V0-01A (Primary Tumor).

[page 1 of 5]
& Neck
And Neck

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right thyroid papillary thyroid cancer, patient for central and right lateral neck dissection.

Specimens Submitted:

- 1: SP: Level 1-B lymph node, right neck (fs)
- 2: SP: Right neck contents level two-A
- 3: SP: Right neck contents level-three
- 4: SP: Right neck contents level-four
- 5: SP: Thyroid, total thyroidectomy
- 6: SP: Right para-tracheal gutter
- 7: SP: Right level seven lymph node
- 8: SP: Left para-tracheal gutter

DIAGNOSIS:

1. LYMPH NODE, LEVEL 1-B LYMPH NODE, RIGHT NECK; LYMPHADENECTOMY:
- ONE BENIGN LYMPH NODE (0/1)
2. LYMPH NODE, RIGHT NECK CONTENTS LEVEL TWO-A; LYMPHADENECTOMY:
- METASTATIC PAPILLARY CARCINOMA IN ONE OF SIX LYMPH NODES (1/6).
- LARGEST LYMPH NODE WITH METASTASIS IS 2 CM AND LARGEST METASTATIC FOCUS IS 2 CM.
- NO EXTRA-NODAL EXTENSION SEEN.
3. LYMPH NODE, RIGHT NECK CONTENTS LEVEL-THREE; LYMPHADENECTOMY:
- METASTATIC PAPILLARY CARCINOMA IN TWO OF TWO LYMPH NODES (2/2).
- LARGEST LYMPH NODE WITH METASTASIS IS 1.1 CM AND LARGEST METASTATIC FOCUS IS 0.6 CM.
- NO EXTRA-NODAL EXTENSION SEEN
- BENIGN SKELETAL MUSCLE
4. LYMPH NODE, RIGHT NECK CONTENTS LEVEL-FOUR; LYMPHADENECTOMY:
- METASTATIC PAPILLARY CARCINOMA IN ONE OF ONE LYMPH NODES (1/1).
- LARGEST LYMPH NODE WITH METASTASIS IS 1 CM AND LARGEST METASTATIC FOCUS IS 0.9 CM.
- NO EXTRA-NODAL EXTENSION SEEN

5. SP: Thyroid, total thyroidectomy:

Tumor Type:

Two foci of papillary carcinoma, tall and classical variants

$\geq 50\%$ Tall cell features, few TSS /lw

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

ICD-O-3

carcinoma, papillary, tall cell

8344/3

Site: thyroid, NOS

C73.9

5-2-12

20

[page 2 of 5]
Tumor Location:

Right lobe
Isthmus

Tumor Size:

Greatest diameter is 2.1 cm.
for the isthmic tumor (classical) and 1.8 cm for the right lobe tumor (tail cell)

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades:peri-thyroid fibroadipose tissue

Surgical Margins:

Tumor is present at inked anterior margin

Tumor Multicentricity:

Additional focus of papillary microcarcinoma in left lobe (0.2 cm)

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

Lymph Nodes:

Perinodal (extracapsular) extension identified

Metastatic papillary carcinoma in three of four lymph nodes (3/4); largest metastatic lymph node is 2.5 mm and largest metastatic focus is 2.5mm

6. LYMPH NODE, RIGHT PARA-TRACHEAL GUTTER; LYMPHADENECTOMY:

- METASTATIC PAPILLARY CARCINOMA IN TWO OF TWO LYMPH NODES (2/2).
- LARGEST LYMPH NODE WITH METASTASIS IS 1.8 CM AND LARGEST METASTATIC FOCUS IS 1.8 CM
- EXTRANODAL EXTENSION IS PRESENT IN SKELETAL MUSCLE.

7. LYMPH NODE, RIGHT LEVEL SEVEN; LYMPHADENECTOMY:

- METASTATIC PAPILLARY CARCINOMA IN ONE OF ONE LYMPH NODE (1/1).
- LARGEST LYMPH NODE WITH METASTASIS IS 1.6 CM AND LARGEST METASTATIC FOCUS IS 1.6 CM
- EXTRANODAL EXTENSION IS PRESENT

8. LYMPH NODE, LEFT PARA-TRACHEAL GUTTER; LYMPHADENECTOMY:

- METASTATIC PAPILLARY CARCINOMA IN THREE OF THREE LYMPH NODES (3/3).
- LARGEST LYMPH NODE WITH METASTASIS IS 0.9 CM AND LARGEST METASTATIC FOCUS IS 0.8 CM
- UNREMARKABLE PARATHYROID GLAND.
- NO EXTRA-NODAL EXTENSION SEEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

[page 3 of 5]
1. The specimen is received fresh in a container labeled "Level 1-B lymph node, right neck". It consists of a lymph node measuring 1.5 x 0.5 x 0.4 cm. The lymph node is bisected and submitted entirely for frozen section.

Summary of Sections:

FSC- frozen section control, bisected lymph node

2.) The specimen is received fresh, labeled "right neck contents, level 2A" and consists of multiple possible lymph nodes ranging from 0.3 cm up to 2.0 cm in greatest dimensions. The largest, grossly positive node is bisected and half is submitted for . All possible lymph nodes are entirely submitted.

Summary of sections:

BLN - remaining half of largest lymph node

LN - lymph nodes

3.) The specimen is received fresh, labeled "right neck contents level 3" and consists of multiple possible lymph nodes ranging from 0.2 cm up to 1.0 cm in greatest dimensions. All possible lymph nodes are entirely submitted.

Summary of sections:

BLN - bisected lymph node

LN - lymph nodes

4.) The specimen is received fresh, labeled "right neck contents level 4" and consists of one lymph nodes measuring 1.1 x 0.6 x 0.5 cm. The lymph node is bisected and entirely submitted.

Summary of sections:

BLN - bisected lymph node

5.) The specimen is received fresh, labeled "total thyroid stitch marks right superior pole" and consists of a thyroid weighing 37 g. The right lobe measures 4.0 x 3.0 x 1.0 cm, the left lobe measures 3.5 x 1.5 x 1.0 cm and the isthmus measures 5.5 x 2.0 x 2.0 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a well circumscribed, partially calcified nodule measuring 1.8 x 1.0 x 0.8 cm in the right lobe and a large, encapsulated, partially cystic mass replacing the entire isthmus. Sections through the remaining tissue reveals no other gross lesions. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

NRL - nodule, right lobe

RL - right lobe

LL - left lobe

ISM - isthmus mass

6.) The specimen is received fresh, labeled "right paratracheal gutter" and consists of multiple possible lymph nodes ranging from 0.2 cm up to 1.8 cm in greatest dimensions. The largest lymph node is grossly positive and is quadrisectioned. All possible lymph nodes are entirely submitted.

Summary of sections:

QLN - largest lymph node quadrisectioned

LN - lymph nodes

[page 4 of 5]
7.) The specimen is received fresh, labeled "right level 7 lymph node" and consists of a grossly positive lymph node measuring 1.6 x 1.4 x 1.0 cm. The lymph node is trisected and entirely submitted.

Summary of sections:

TLN - trisected lymph node

8.) The specimen is received fresh, labeled "left paratracheal gutter" and consists of four lymph nodes ranging from 0.2 cm up to 1.0 cm in greatest dimensions. The largest lymph node is bisected. All possible lymph nodes are entirely submitted.

Summary of sections:

BLN - bisected lymph node

LN - lymph nodes

Summary of Sections:

Part 1: SP: Level 1-B lymph node, right neck (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: SP: Right neck contents level two-A

Block	Sect. Site	PCs
4	ADD	11
1	BLN	1
1	LN	1

Part 3: SP: Right neck contents level-three

Block	Sect. Site	PCs
10	ADD	23
2	BLN	2
1	LN	1

Part 4: SP: Right neck contents level-four

Block	Sect. Site	PCs
11	ADD	21
1	BLN	1

Part 5: SP: Thyroid, total thyroidectomy

Block	Sect. Site	PCs
6	ISM	6
5	LL	5
2	NRL	2
3	RL	3

Part 6: SP: Right para-tracheal gutter

Block	Sect. Site	PCs
3	ADD	9
1	LN	1
2	QLN	2

Part 7: SP: Right level seven lymph node

[page 5 of 5]
Block	Sect. Site	PCs
3	TLN	3

Part 8: SP: Left para-tracheal gutter

Block	Sect. Site	PCs
4	ADD	12
1	BLN	1
1	LN	1

Procedures/Addenda:

Addendum

Date Ordered:
Date Complete:
Date Reported: 11

Status: Signed Out

Addendum Diagnosis

ALL REMAINING TISSUE FROM PARTS 2,3,4,6,8 WAS SUBMITTED AND SHOWS THE FOLLOWING:

2. SP: RIGHT NECK CONTENTS LEVEL TWO-A:
-TEN ADDITIONAL BENIGN LYMPH NODES (0/10).
3. SP: RIGHT NECK CONTENTS LEVEL-THREE:
-EIGHTEEN ADDITIONAL BENIGN LYMPH NODES (0/18)
4. SP: RIGHT NECK CONTENTS LEVEL-FOUR:
-BENIGN SKELETAL MUSCLE AND FIBROADIPOSE TISSUE.
6. SP: RIGHT PARA-TRACHEAL GUTTER:
-BENIGN FIBROADIPOSE TISSUE.
8. SP: LEFT PARA-TRACHEAL GUTTER:
- TWO ADDITIONAL BENIGN LYMPH NODES (0/2).
-BENIGN THYMIC TISSUE

*** Report Electronically Signed Out **
Signed out by: [REDACTED]

Intraoperative Consultation:

1. SP: Level 1-B lymph node, right neck (fs): benign
Permanent: Same

Source: NCI Genomic Data Commons file 0cb21598-4322-42af-a234-f33a695ebe07 (TCGA-DJ-A3V0.F391F61B-413E-445F-A4AB-E6EA65B57DB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).